Somatic mutation profile of tumor specimen 0DFKHH from CCDI case PBBSFF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.8 years (6,126 days).
Specimen 0DFKHH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a7ebeaa-db74-44b4-a202-1d05dfd6d920.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFKHJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2fd0e42-f837-4e2b-bef8-ab68147de68c

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 205/947 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EXD3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 39/625 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs759697078, COSV59808238; called by muse, mutect2
- MAP3K11 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 68/904 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.368); catalogued as rs376240928; called by muse, mutect2
- NF1 | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 364/1570 reads (23%) | catalogued as COSV62192113; called by muse, mutect2, varscan2
- FGF16 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 64/1302 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 22/896 reads (2%) | called by muse, mutect2
- RPL3 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 64/1518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- WDR59 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 52/1531 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ITGA6 | c.2967T>A p.L989= (on ENST00000442250; = p.L950= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/1251 reads (4%) | called by muse, mutect2
- NCOA5 | c.1194G>A p.S398= | Silent (SNP) | VAF 106/1028 reads (10%) | catalogued as rs750675389; called by muse, mutect2, varscan2
